Gene-level copy-number profile of tumor specimen TCGA-13-1496-01A from TCGA case TCGA-13-1496, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.7 years (23,993 days).
Specimen TCGA-13-1496-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.1b6ac59f-1dcb-4473-9af6-27d0d869f05e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1496-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c00670c3-3dfb-4177-9ed9-f74a48c10055

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 179; copy number 2: 13,206; copy number 3: 22,371; copy number 4: 17,453; copy number 5: 3,436; copy number 6: 1,658; copy number 7: 462; copy number 8: 163; copy number 9: 66; copy number 10: 636; copy number 11: 18; copy number 12: 24; copy number 14: 68; copy number 16: 6; copy number 17: 20; copy number 19: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1496-01A-01D-0472-01): tumor purity 0.8, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,430 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–151,267,479, 304 genes, copy number 7 (broad region; genes not listed).
- chr2:37,641,882–38,231,651, 11 genes, copy number 8 (within-gene range 3–8): CDC42EP3, AC006369.2, AC010878.1, LINC00211, RMDN2, RMDN2-AS1, CYP1B1, CYP1B1-AS1, AC009229.4, AC009229.2, RNU6-951P.
- chr2:53,470,447–56,750,563, 59 genes, copy number 7: AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5, RNU6-775P, RNU6-221P, RNU6-634P, CFAP36, PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813, AC007744.1, AC007743.1, CCDC85A, RNA5SP93, PPIAP63.
- chr2:59,014,354–62,662,829, 76 genes, copy number 7–11 (broad region; genes not listed).
- chr5:35,852,695–36,485,440, 17 genes, copy number 7: IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181.
- chr5:44,808,947–44,828,592, 2 genes, copy number 11: MRPS30, AC093297.2.
- chr8:54,420,468–54,871,720, 7 genes, copy number 14: RN7SL250P, SOX17, AC091076.1, TRMT112P7, RP1, SEC11B, AC090151.1.
- chr8:125,430,358–131,712,980, 79 genes, copy number 11–19 (within-gene range 9–19) (broad region; genes not listed).
- chr12:127,372,243–127,372,669, 1 gene, copy number 7: AC048347.1.
- chr18:50,375,040–50,394,168, 1 gene, copy number 7: SKA1.
- chr19:13,731,760–13,778,773, 4 genes, copy number 8: CCDC130, MRI1, AC008686.1, C19orf53.
- chr19:13,796,574–13,796,933, 1 gene, copy number 8: AC020916.2.
- chr19:15,979,835–17,075,625, 60 genes, copy number 7: CYP4F9P, LINC00661, AC004790.2, LINC00905, SNX33P1, AC004790.1, OR1AB1P, LINC01855, TPM4, AC008894.3, AC008894.1, RAB8A, AC008894.2, HSH2D, CIB3, FAM32A, AC020911.1, Metazoa_SRP, AC020911.3, AP1M1, AC020911.2, KLF2, AC020917.3, EPS15L1, AC020917.4, AC020917.1, AC020917.2, CALR3, AC008764.1, C19orf44, CHERP, RN7SL146P, AC008764.6, SLC35E1, AC008764.3, AC008764.5, AC008764.8, MED26, AC008764.4, AC008764.7, AC008764.9, AC008764.10, AC008764.2, AC024075.3, SMIM7, AC024075.2, AC024075.1, TMEM38A, AC008737.2, NWD1, AC008737.3, SIN3B, AC008737.1, F2RL3, CPAMD8, RN7SL835P, RN7SL823P, AC020908.2, HAUS8, AC020908.1.
- chr19:29,606,283–37,587,348, 287 genes, copy number 10–14 (within-gene range 3–14) (broad region; genes not listed).
- chr19:37,554,782–37,594,792, 1 gene, copy number 10 (within-gene range 4–10): ZNF571.
- chr19:38,730,187–40,122,168, 87 genes, copy number 8 (broad region; genes not listed).
- chr19:51,345,169–56,848,556, 433 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 179. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
